Surgical pathology report (de-identified scan), TCGA case TCGA-QC-AA9N, project TCGA-SARC (Sarcoma), tissue source site Emory University, specimen TCGA-QC-AA9N-01A (Primary Tumor).

[page 1 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

arding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

(Verified)

ICD-C-3
Sarcoma, pleomorphic, undifferentiated
(8802/3) (8805/3)
Code to highest 8805/3
Site @ Buttock NOS C49.5
9/21/14

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender:

F

Acc #:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. SKIN AND SOFT TISSUE, RIGHT BUTTOCK; RADICAL RESECTION:

- UNDIFFERENTIATED PLEOMORPHIC SARCOMA, HIGH-GRADE; SEE SYNOPTIC REPORT
- MARGINS NEGATIVE FOR TUMOR

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Radical resection sarcoma, right buttock, short stitch - superior; long stitch - lateral:

Preresection Treatment:

No therapy

Procedure:

Radical resection

Printed by:

Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Anat Path Reports

* Final Report *

Tumor Site:	Right gluteal subcutaneous tissue
Histologic Type:	Undifferentiated pleomorphic sarcoma
Histologic Grade:	Grade 3
Macroscopic Extent of Tumor:	Superficial - Subcutaneous/suprafascial
Tumor Size:	Greatest dimension: 10.0 cm
Margins:	Margins negative for sarcoma Distance of sarcoma from closest margin: 1.6 cm Margin: deep Other close (less than 2.0 cm) margin(s): inferior (1.9 cm)
Mitotic Rate:	30 /10 high-power fields (HPF)
Necrosis:	Present Extent: 30%
Treatment Effect:	Not identified
Immunohistochemistry:	Not performed
Cytogenetics:	Not performed
Molecular Pathology:	Not performed
TNM Descriptors:	Not applicable
Primary Tumor:	pT2a: Tumor more than 5 cm in greatest dimension, superficial tumor
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Number of nodes examined: 0 Number of nodes positive: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None

Clinical History

Radical excision, right buttocks sarcoma. Right buttocks sarcoma.

Specimen(s) Received

A: Radical resection sarcoma, right buttock, short stitch - superior; long stitch - lateral

Gross Description

The specimen is received fresh, labeled with the patient's name, medical record number and designated "radical resection sarcoma, right buttocks." It consists of an elliptical excision of skin with attached underlying soft tissue and weighing 1119.5 grams. There is a long stitch at one of the elliptical tips designating the lateral margin and a short stitch at the mid point between the two elliptical tips designating the superior margin. The skin ellipse measures as follows: superior to inferior, 5.4 cm; lateral to medial, 16.0 cm. The underlying soft tissue measures superior to inferior 13.0 cm, medial to lateral 20.0 cm and is excised to a maximum depth of 11.0 cm. The deep margin is partially covered with unremarkable muscle.

Sectioning demonstrates a well-circumscribed, heterogenous, lobulated, solid mass, 3.0 cm below the epidermal surface and measuring 10.0 x 9.1 x 8.3 cm. The mass is tan-white, focally hemorrhagic with approximately 5% tumor necrosis. The mass is 1.4 cm from the deep margin, 5.5 cm from the medial tip, 6.2 cm from the lateral tip, 3.3 cm from the superior margin and 1.9 cm from the inferior margin. No other lesions are identified.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

The soft tissue away from this mass is composed of unremarkable, soft, lobulated, fibrofatty tissue. A representative section of the mass as well as uninvolved soft tissue is submitted to Tissue Procurement Services. Representative sections are submitted as stated below. Dictated by

Ink code:

Deep – black
Superior – blue
Inferior – green
Medial – orange
Lateral – red

CASSETTE SUMMARY:

A1 – medial tip, shave
A2 – lateral tip, shave
A3 – anterior surface closest to mass
A4 – deep margin, closest to mass
A5 – superior margin, closest to mass
A6 – inferior margin, closest to mass, bisected
A7-A11 – representative mass

Microscopic Description

Microscopic examination performed

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file d68ff19b-b94f-41b9-8132-703808c5583c (TCGA-QC-AA9N.AFA6DD2C-98CA-4E96-BD89-164FD5D3FCE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).